Surgical pathology report (de-identified scan), TCGA case TCGA-BT-A2LB, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BT-A2LB-01A (Primary Tumor).

Collection Date:

FINAL DIAGNOSIS:

PART 1: URETER, RIGHT, MARGIN, BIOPSY -

- A. SEGMENT OF URETER LINED BY BENIGN REACTIVE UROTHELIUM.
- B. NO UROTHELIAL CARCINOMA IN SITU (CIS) NOR INVASIVE UROTHELIAL CARCINOMA SEEN.

PART 2: URETER, LEFT, MARGIN, BIOPSY -

- A. SEGMENT OF URETER LINED BY BENIGN REACTIVE UROTHELIUM.
- B. NO UROTHELIAL CARCINOMA IN SITU (CIS) NOR INVASIVE UROTHELIAL CARCINOMA SEEN.

PART 3: URINARY BLADDER, BLADDER NECK, BIOPSY -

- A. BENIGN FIBROMUSCULAR TISSUE WITH FOCAL REACTIVE UROTHELIUM.
- B. NO EVIDENCE OF MALIGNANCY.

PART 4:

BLADDER, VAGINA, UTERUS, BILATERAL OVARIES AND FALLOPIAN TUBES, ANTERIOR PELVIC EXENTERATION -

- A. MULTIFOCAL INVASIVE UROTHELIAL CARCINOMA, HIGH GRADE (WHO/ISUP).
- B. THE CARCINOMA MEASURES 2.1 CM IN GREATEST DIMENSION.
- C. THE CARCINOMA EXTENSIVELY INVOLVES THE DETRUSOR MUSCLE AND INVADERS INTO THE PERIVESICAL ADIPOSE TISSUE.
- D. ALL SURGICAL MARGINS OF RESECTION ARE FREE OF CARCINOMA.
- E. UROTHELIAL CARCINOMA IN SITU (CIS) IS IDENTIFIED.
- F. PERINEURAL INVASION IS IDENTIFIED.
- G. ANGIOLYMPHATIC INVASION IS IDENTIFIED (SLIDE 4G).
- H. UTERUS, BILATERAL OVARIES AND FALLOPIAN TUBES WITH NO SIGNIFICANT PATHOLOGIC ABNORMALITY.
- I. TNM PATHOLOGIC STAGING (AJCC 7TH EDITION): pT3a N0 MX.

PART 5: LYMPH NODES, RIGHT PELVIC, EXCISION -

NO EVIDENCE OF MALIGNANCY IN SEVEN LYMPH NODES EXAMINED (0/7).

PART 6: LYMPH NODE, LEFT PELVIC, EXCISION -

NO EVIDENCE OF MALIGNANCY IN SEVEN LYMPH NODES EXAMINED (0/7).

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY URINARY BLADDER TUMORS

SPECIMEN TYPE:

TUMOR SITE:

TUMOR SIZE:

HISTOLOGIC TYPE:

ASSOCIATED EPITHELIAL LESIONS:

HISTOLOGIC GRADE:

TUMOR CONFIGURATION:

PATHOLOGIC STAGING (pTNM):

Anterior exenteration
Right lateral wall, Dome
Greatest dimension: 2.1 cm
Additional dimensions: 1.4 x 1.2 and 0.6 x 0.5 x 0.3 cm
Urothelial (transitional cell) carcinoma
None identified
Urothelial carcinoma - High-grade
Solid/nodule, Ulcerated
pT3a
pN0

Number of nodes examined: 14
Number of nodes involved: 0

PMX

MARGINS:

Margins uninvolved by invasive carcinoma

VENOUS/LYMPHATIC (LARGE/SMALL) VESSEL INVASION (V/L):

Present

DIRECT EXTENSION OF INVASIVE TUMOR:

Perivesical fat

ADDITIONAL PATHOLOGIC FINDINGS:

Urothelial carcinoma in situ

ICD-0-3

Carcinoma, urothelial, nos

8/20/3

Site: Path: bladder nos

C67.9

CQCF: bladder, dome

C67.1

hw
8/19/11

Source: NCI Genomic Data Commons file 3cd74b13-dd29-458f-9e4b-fc98566718f0 (TCGA-BT-A2LB.CD9D52D3-87E7-4AC0-BBEA-E22C57F2E10A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).